Surgical pathology report (de-identified scan), TCGA case TCGA-X7-A8M7, project TCGA-THYM (Thymoma), tissue source site ABS IUPUI, specimen TCGA-X7-A8M7-01A (Primary Tumor).

Operative Procedure:
Thymectomy

Pre-Operative Diagnosis:
As below

Post-Operative Diagnosis:
As below

Specimen Received:
Mediastinal mass

Final Pathologic Diagnosis:
Thymus, anterior mediastinum, excision:
Cortical thymoma, (B2 in WHO classification).
- encapsulated.
- surgical margins free of tumor (excised).
- no lymphatic or vascular invasion.
- pericardium present, not involved.
- pT1, Nx, Mx

The examination of this case material and the preparation of this report were performed by the staff pathologist.

Gross Description:

Received is a single formalin filled container labeled with the patient's name, and "mediastinal mass." The specimen consists of a 14 x 7 x 2 cm portion of yellow-tan fibrofatty tissue with an eccentrically located 7 x 4 x 2 cm soft tissue mass. The specimen is inked and sectioned to reveal the mass to be well circumscribed with a gray-tan, nodular, soft cut surface. The remainder of the tissue has a yellow-tan, lobulated cut surface with no additional lesions identified.

Sections are submitted as follows:

- 1-5 representative sections of mass;
- 6-7 representative sections of additional tissue.

Microscopic Description:

Sections show a cortical (lymphocyte rich) thymoma that focally extends into but not through the capsule. It appears to be completely excised. There is a portion of adhered pericardium, but the pericardium is not invaded by the tumor. The surrounding thymus does not show lymphoid hyperplasia. There is a component of thymic cyst

Surgical Pathology Report

Taken: DOB: (Age: Gender: M Race: White

ICD-O 3
Thymoma, type B2 (cortical)
malignant 8584/3
Site: Anterior mediastinum C38.1
9/26/10/14

Source: NCI Genomic Data Commons file 61c6a44d-af3f-466d-8375-e135eb733788 (TCGA-X7-A8M7.5AA91893-D6C3-4FC6-8F4B-6D01F8FAEF14.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).